Gene-level copy-number profile of tumor specimen TCGA-D9-A3Z4-01A from TCGA case TCGA-D9-A3Z4, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 54.1 years (19,749 days).
Specimen TCGA-D9-A3Z4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.bdab5039-ebe1-4475-99ce-907aecc0ed65.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D9-A3Z4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/008f3520-dbce-47ba-93f9-a9fcd8377b52

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 2: 12,945; copy number 3: 2,886; copy number 4: 38,261; copy number 5: 135; copy number 6: 2,008; copy number 7: 19; copy number 8: 4; copy number 9: 1,732; copy number 10: 485; copy number 11: 1,085; copy number 12: 247.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D9-A3Z4-01A-11D-A238-01): tumor purity 0.68, ploidy 3.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,128,103, 7 genes (within-gene range 0–2): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr21:46,458,891–46,665,124, 6 genes: DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,549 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–208,736,286, 1,732 genes, copy number 9 (broad region; genes not listed).
- chr1:237,862,175–248,919,946, 270 genes, copy number 10 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 10–12 (broad region; genes not listed).
- chr21:19,345,148–20,598,163, 13 genes, copy number 11: RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
